Gene-level copy-number profile of tumor specimen ALCH-B28C-TTP1-A from ALCHEMIST case ALCH-B28C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.1 years (23,415 days).
Specimen ALCH-B28C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 01509b5b-8ce1-4749-81f3-3d145219e663.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B28C-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/0d22ba6f-58b8-43c5-94b2-542aa93f361b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 6,585; copy number 2: 49,500; copy number 3: 1,419; copy number 4: 461; copy number 5: 84; copy number 6: 59; copy number 7: 138; copy number 8: 14; copy number 9: 53; copy number 10: 3; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,425,257–11,425,821, 1 gene: MTCYBP45.
- chr1:55,039,447–55,064,852, 1 gene: PCSK9.
- chr2:23,507,043–23,524,344, 1 gene (within-gene range 0–1): AC011239.1.
- chr2:232,442,034–232,447,418, 1 gene: DIS3L2P1.
- chr3:43,778,961–43,779,982, 1 gene: AC006055.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr7:27,128,969–27,157,936, 6 genes (within-gene range 0–2): AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7.
- chr7:27,162,438–27,180,261, 5 genes: HOXA9, AC004080.3, HOXA10-AS, MIR196B, HOXA10.
- chr9:121,444,991–121,785,530, 5 genes (within-gene range 0–2): GGTA1, RN7SL187P, HMGB1P37, DAB2IP, AL357936.1.
- chr12:190,077–214,570, 3 genes (within-gene range 0–1): SLC6A12, AC007406.1, SLC6A12-AS1.
- chr15:25,178,738–25,241,827, 35 genes (within-gene range 0–1): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:24,004,358–24,163,425, 7 genes: RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 352 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:33,576,095–33,576,200, 1 gene, copy number 5: RNU6-400P.
- chr12:57,253,762–58,395,138, 56 genes, copy number 6 (within-gene range 4–6): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:62,643,994–62,935,150, 1 gene, copy number 7 (within-gene range 4–7): PPM1H.
- chr12:62,755,227–75,209,839, 228 genes, copy number 5–9 (broad region; genes not listed).
- chr13:99,181,223–99,200,757, 1 gene, copy number 5 (within-gene range 2–5): UBAC2-AS1.
- chr14:105,472,962–105,480,162, 1 gene, copy number 6: CRIP2.
- chr19:1,103,926–1,106,791, 1 gene, copy number 5: GPX4.
- chr21:43,414,483–43,479,534, 4 genes, copy number 10–21: SIK1, LINC00319, LINC00313, AP001048.1.
- chr22:42,058,334–43,892,013, 59 genes, copy number 5–9 (within-gene range 3–9): NAGA, PHETA2, SNORD13P1, SMDT1, NDUFA6, AL021878.4, NDUFA6-DT, OLA1P1, CYP2D6, AC254562.1, AC254562.2, AC254562.3, CYP2D7, CYP2D8P, TCF20, OGFRP1, LINC01315, NFAM1, AL022316.1, SERHL, RRP7A, SERHL2, RRP7BP, RN7SKP80, RNU6-513P, POLDIP3, RNU12, Z93241.1, CYB5R3, ATP5MGL, A4GALT, Y_RNA, RPL5P34, GOLGA2P4, AL049757.1, ARFGAP3, PACSIN2, AL049758.1, TTLL1-AS1, TTLL1, AL022237.1, BIK, MCAT, TSPO, TTLL12, SCUBE1, SCUBE1-AS2, Z82214.1, SCUBE1-AS1, LINC01639, MPPED1, BX546033.1, EFCAB6-AS1, EFCAB6, Z97055.1, HMGN2P9, Z97055.2, SULT4A1, PNPLA5.

Autosomal genes at a single copy (total copy number 1): 6,551. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
